Somatic mutation profile of tumor specimen TCGA-BT-A20W-01A (aliquot TCGA-BT-A20W-01A-21D-A14W-08) from TCGA case TCGA-BT-A20W, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 71.4 years (26,078 days).
Specimen TCGA-BT-A20W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16cdb054-5e59-4d83-b826-fe42f3f4af4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BT-A20W-11A (Solid Tissue Normal), aliquot TCGA-BT-A20W-11A-11D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7115c1b-d36b-4728-ab73-01bf79dd0195

The open-access MAF lists 72 somatic variants for this specimen: 55 protein-altering or splice-affecting, 17 silent.
By variant classification: Missense Mutation 50, Silent 17, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 11/123 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ASCC3 | c.5794G>A p.A1932T | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64977744; called by muse, mutect2
- ATP6V0A1 | c.1867T>C p.S623P | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV52875741; called by muse, mutect2
- BRCA1 | c.2708G>C p.C903S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.326); catalogued as COSV58794490; called by muse, mutect2, varscan2
- C1orf158 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.99); catalogued as COSV55347327; called by muse, mutect2
- CABS1 | c.238G>C p.D80H | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV56733220; called by muse, mutect2
- CASP4 | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as COSV67744363, COSV67744632; called by muse, mutect2
- CASP4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.052); catalogued as rs1030418546, COSV67744181, COSV67744639; called by muse, mutect2
- CHSY3 | c.1925A>G p.E642G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59281869; called by muse, mutect2
- COIL | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs1385390320; called by muse, mutect2
- COL5A1 | c.728A>T p.D243V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65671927; called by muse, mutect2
- CUL2 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.351); catalogued as rs1297084086, COSV66079849; called by muse, mutect2, varscan2
- DCHS1 | c.1654G>A p.D552N | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778093381, COSV55033999, COSV55034357; called by muse, mutect2, varscan2
- DHX33 | c.625G>C p.V209L | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.147); catalogued as COSV56579954; called by muse, mutect2
- DNAH5 | c.10679A>T p.N3560I | Missense Mutation (SNP) | VAF 10/277 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV54238907; called by muse, mutect2
- EPRS1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 11/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194185772, COSV65098335; called by muse, mutect2
- FAM126A | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.927); catalogued as COSV69017451; called by muse, mutect2
- FBXO40 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs1342710359; called by muse, mutect2
- FKBP7 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV51846951; called by muse, mutect2
- HK1 | c.1989G>A p.M663I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as COSV53861919; called by muse, mutect2
- HTR2B | c.526A>C p.I176L | Missense Mutation (SNP) | VAF 17/259 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV51450273; called by muse, mutect2
- IMPG2 | c.3631G>C p.E1211Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as COSV51981991; called by muse, mutect2, varscan2
- IYD | c.456C>G p.I152M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57599712, COSV57602501, COSV57604375; called by mutect2, varscan2
- KIAA1109 | c.3880C>G p.Q1294E | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.266); catalogued as COSV52682628; called by muse, varscan2
- LMO7 | c.3292G>A p.E1098K (on ENST00000357063; = p.E779K on NM_005358.5) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV58541998; called by muse, mutect2
- LRRC6 | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 8/241 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.035); catalogued as COSV51544579; called by muse, mutect2
- MMRN1 | c.3131G>T p.S1044I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.039); catalogued as COSV53340054; called by muse, mutect2
- MUC16 | c.6002C>G p.S2001* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as rs1459666413, COSV67506677; called by muse, mutect2, varscan2
- NCOR2 | c.6849G>C p.K2283N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62300711; called by muse, mutect2
- NEK5 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs267603847, COSV62879653; called by muse, mutect2, varscan2
- NKTR | c.2900C>T p.S967L | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV51771023; called by muse, mutect2
- OPCML | c.667C>T p.P223S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV59412505; called by muse, mutect2
- OR6T1 | c.674T>C p.V225A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV58308275; called by muse, mutect2, varscan2
- PRCP | c.1194G>C p.W398C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57289968; called by muse, mutect2, varscan2
- PTPRU | c.4175C>T p.A1392V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV60532061; called by muse, mutect2, varscan2
- RAPGEF4 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV51402134; called by muse, mutect2
- REEP2 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1302842805, COSV54735491; called by muse, mutect2
- RUSC1 | c.1513G>A p.A505T (on ENST00000368352 / NM_001105203.2; = p.A36T on NM_014328.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/183 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV52741316; called by muse, mutect2, varscan2
- SACS | c.11759G>C p.S3920T | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as COSV66543736; called by muse, mutect2
- SAMD4B | c.769G>C p.G257R | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.921); catalogued as COSV58752407; called by muse, mutect2, varscan2
- SEC23IP | c.1701G>C p.M567I | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV64832255; called by mutect2, varscan2
- SGO1 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV55424437; called by muse, mutect2, varscan2
- SMC4 | c.2710G>C p.D904H | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV61004282, COSV61006417; called by muse, mutect2
- SORCS1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1486573405, COSV53845136; called by muse, mutect2, varscan2
- SPNS1 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57955216; called by muse, mutect2
- ST8SIA2 | c.287T>A p.I96N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | PolyPhen possibly damaging (0.868); catalogued as COSV51571116, COSV51571200; called by muse, mutect2, varscan2
- TENM1 | c.4438G>C p.D1480H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV64437306; called by muse, mutect2, varscan2
- ZNF99 | c.863A>C p.E288A | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV68056138; called by muse, mutect2
- AKAP9 | c.10413dup p.L3472Tfs*10 (on ENST00000359028; = p.L3448Tfs*10 on NM_005751.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- ATP6V0A1 | c.1116T>G p.Y372* | Nonsense Mutation (SNP) | VAF 14/151 reads (9%) | called by muse, mutect2, varscan2
- GOLGA6A | c.1462C>A p.L488I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); called by mutect2, varscan2
- MAP4K1 | c.2221G>T p.G741* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- NRXN1 | c.2846G>C p.G949A | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2
- NTS | c.211_215del p.P71* | Frame Shift Del (DEL) | VAF 12/148 reads (8%) | called by mutect2, pindel
- RNFT2 | c.1172T>C p.F391S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2
- ARL4C | c.72C>T p.A24= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- BACH1 | c.972T>G p.S324= | Silent (SNP) | VAF 11/317 reads (3%) | catalogued as COSV54519894; called by muse, mutect2
- C11orf87 | c.216C>T p.F72= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV59357651; called by muse, mutect2, varscan2
- DRG1 | c.456G>A p.L152= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV58919343; called by muse, mutect2
- FBXO27 | c.834G>C p.V278= | Silent (SNP) | VAF 6/132 reads (5%) | catalogued as COSV53072808; called by muse, mutect2
- FLT4 | c.450G>A p.R150= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV56115438; called by muse, mutect2, varscan2
- KCNA1 | c.162C>A p.T54= | Silent (SNP) | VAF 24/78 reads (31%) | catalogued as COSV66838067; called by muse, mutect2, varscan2
- LILRB5 | c.924C>T p.P308= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs976842707; called by muse, mutect2
- NEURL4 | c.2481G>T p.A827= | Silent (SNP) | VAF 7/48 reads (15%) | catalogued as COSV59751391, COSV59751688; called by muse, mutect2, varscan2
- PRAG1 | c.2919C>T p.L973= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100422063, COSV58164124; called by muse, mutect2, varscan2
- QKI | c.837C>T p.P279= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs569768147, COSV51697403, COSV99273985; called by muse, mutect2, varscan2
- RNF20 | c.1563G>A p.Q521= | Silent (SNP) | VAF 10/268 reads (4%) | catalogued as COSV66661685; called by muse, mutect2
- SEC63 | c.2160G>A p.K720= | Silent (SNP) | VAF 9/106 reads (8%) | catalogued as COSV64601002; called by muse, mutect2
- SLC6A14 | c.387A>G p.T129= | Silent (SNP) | VAF 14/103 reads (14%) | catalogued as rs782810098, COSV64147787; called by muse, mutect2, varscan2
- TBC1D4 | c.948C>T p.C316= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV66490282; called by muse, mutect2
- TTF1 | c.1248C>T p.S416= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV57505879; called by muse, mutect2
- ZFAT | c.927C>A p.A309= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as COSV64742073; called by muse, mutect2
